Somatic mutation profile of tumor specimen TARGET-10-PARWID-09A (aliquot TARGET-10-PARWID-09A-01D) from TARGET case TARGET-10-PARWID, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.3 years (7,053 days).
Specimen TARGET-10-PARWID-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1761beb5-3232-4231-a544-0f8afcabc2a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARWID-10A (Blood Derived Normal), aliquot TARGET-10-PARWID-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9e96d04-c00e-4b7d-86d1-47cbd81cf91c

The open-access MAF lists 31 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Nonsense Mutation 3, Frame Shift Del 3, Intron 3, 5'Flank 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1483636261; called by muse, mutect2
- ARHGAP18 | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV63765907; called by muse, mutect2, varscan2
- IGSF3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs200995544, COSV59597511; called by muse, mutect2, varscan2
- MAGEC1 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.167); catalogued as rs773789570, COSV53580046; called by muse, mutect2
- NOTCH1 | c.4752_4753insGGTCCTGAG p.Q1584_L1585insGPE | In Frame Ins (INS) | VAF 11/28 reads (39%) | catalogued as COSV53050150; called by mutect2, varscan2
- OR2T3 | c.650T>A p.M217K | Missense Mutation (SNP) | VAF 93/109 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV62082834, COSV62083504; called by muse, mutect2, varscan2
- PI4K2A | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as rs1205523013; called by muse, mutect2
- SPTA1 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs147573740, COSV100934898; called by muse, mutect2, varscan2
- ST7 | c.1411C>T p.R471W (on ENST00000265437 / NM_021908.3; = p.R448W on NM_018412.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772278439, COSV55380371; called by muse, mutect2, varscan2
- ZDHHC8 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57712704; called by muse, mutect2, varscan2
- ZFYVE16 | c.1917_1918del p.N640Qfs*10 | Frame Shift Del (DEL) | VAF 70/158 reads (44%) | catalogued as COSV62017282; called by mutect2, pindel, varscan2
- ZNF526 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as COSV55900689; called by muse, mutect2, varscan2
- FSTL5 | c.399C>A p.C133* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- GRID1 | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2
- NOTCH1 | c.7406del p.P2469Hfs*8 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | called by mutect2, varscan2
- PEAK3 | c.1350G>A p.W450* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- RUNX1 | c.879_883delinsG p.L294Qfs*6 (on ENST00000344691 / NM_001001890.3; = p.L321Qfs*6 on NM_001754.5) | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2*
- SERPINA12 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- AC097637.1 | c.363G>A p.P121= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs1273253916; called by muse, mutect2, varscan2
- FAM171A1 | c.2499G>A p.E833= | Silent (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- MBP | c.345C>T p.D115= | Silent (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- MDGA2 | c.1411T>C p.L471= (on ENST00000399232 / NM_001113498.2; = p.L173= on NM_182830.4) | Silent (SNP) | VAF 108/226 reads (48%) | catalogued as COSV62098126; called by muse, mutect2, varscan2
- MISP | c.1359G>A p.A453= | Silent (SNP) | VAF 92/157 reads (59%) | catalogued as rs535976351; called by muse, mutect2, varscan2
- TAS2R16 | c.99C>A p.G33= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as rs1238036417; called by muse, mutect2
- TMEM233 | c.126C>A p.I42= | Silent (SNP) | VAF 81/176 reads (46%) | called by muse, mutect2, varscan2
- ZNF142 | c.4335G>A p.L1445= (on ENST00000411696 / NM_001379660.1; = p.L1245= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as rs1422237228; called by muse, mutect2, varscan2
- AC123912.3 | n.675C>T | RNA (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- DENND1C | c.825+31C>T | Intron (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- MPV17L2 | c.358+114G>A | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- MRPL46 | c.589+60T>A | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532778 T>A | 5'Flank (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
